Surgical pathology report (de-identified scan), TCGA case TCGA-61-2008, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2008-01A (Primary Tumor).

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

TUMOR LOCATION:	Bilateral
PROCEDURE:	TAH with salpingo-oophorectomy
TUMOR SIZE:	Maximum dimension: 11.8 cm
TUMOR TYPE:	Papillary serous carcinoma
HISTOLOGIC SILVERBERG GRADE:	Moderately differentiated (6-7 pts)
ARCHITECTURAL PATTERN:	Papillary (2)
CYTOLOGIC ATYPIA:	Moderate (2)
MITOTIC COUNTS / 10hpf:	> or = 25 (3)
VASCULAR INVASION:	Yes
TUMOR CAPSULE:	Ruptured
SURFACE IMPLANTS:	Invasive
SURFACE IMPLANT SITE:	Fallopian Tubes
SURFACE IMPLANT SIZE:	> 2 cm.
MALIGNANT CELLS IN ASCITES OR PERITONEAL WASHING:	Yes
LYMPH NODES EXAMINED:	Total number of lymph nodes examined: 20
LYMPH NODES POSITIVE:	Number of positive lymph nodes, Right: 0 Number of positive lymph nodes, Left: 0
T STAGE, PATHOLOGIC:	pT2c
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
FIGO STAGE:	IIC

Source: NCI Genomic Data Commons file b63f04ad-0ddd-4929-b023-9a1ff43ffee3 (TCGA-61-2008.25448427-9A2C-4C36-BC9D-40A82D6E3710.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).